Somatic mutation profile of tumor specimen TCGA-NF-A4X2-01A (aliquot TCGA-NF-A4X2-01A-11D-A28R-08) from TCGA case TCGA-NF-A4X2, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Uterus, NOS; FIGO stage: Stage II; Age at diagnosis: 60.0 years (21,908 days).
Specimen TCGA-NF-A4X2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6180faae-de00-46de-b0d6-45d507d03115.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NF-A4X2-10A (Blood Derived Normal), aliquot TCGA-NF-A4X2-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/09904082-b195-455c-b8b8-f6e54cb1abd3

The open-access MAF lists 105 somatic variants for this specimen: 81 protein-altering or splice-affecting, 21 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 21, Nonsense Mutation 5, Frame Shift Ins 5, Frame Shift Del 4, In Frame Del 2, 5'UTR 1, Intron 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PPP2R1A | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 59/110 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519946, COSV59042187, COSV59042498; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.377C>A p.A126D | Missense Mutation (SNP) | VAF 89/144 reads (62%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64290343, COSV64290444, COSV64294220; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 26/26 reads (100%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.6341C>A p.P2114Q | Missense Mutation (SNP) | VAF 60/207 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61371709; called by muse, mutect2, varscan2
- ARMC8 | c.224C>T p.S75L (on ENST00000469044 / NM_001363941.2; = p.S61L on NM_014154.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/50 reads (76%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.977); catalogued as COSV61768893; called by muse, mutect2, varscan2
- ATP11A | c.1571C>T p.T524I | Missense Mutation (SNP) | VAF 54/284 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.058); catalogued as rs757349490; called by muse, mutect2, varscan2
- CACNA1H | c.1361G>A p.G454D | Missense Mutation (SNP) | VAF 12/12 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763744269; called by muse, varscan2
- CDH2 | c.820G>T p.G274W | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as COSV52283160; called by muse, mutect2, varscan2
- CUX2 | c.4025C>G p.P1342R | Missense Mutation (SNP) | VAF 44/201 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV99921075; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.731A>G p.Y244C (on ENST00000354667 / NM_031243.3; = p.Y232C on NM_002137.4) | Missense Mutation (SNP) | VAF 59/81 reads (73%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.669); catalogued as rs775496049; called by muse, mutect2, varscan2
- LINGO2 | c.1085G>A p.R362H | Missense Mutation (SNP) | VAF 33/39 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1471771066, COSV58056542; called by muse, mutect2, varscan2
- MAN2A1 | c.1520A>G p.Y507C | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752374726; called by muse, mutect2, varscan2
- MCEMP1 | c.265C>T p.L89F | Missense Mutation (SNP) | VAF 31/219 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.372); catalogued as rs775699625, COSV58040806; called by muse, mutect2, varscan2
- MUC17 | c.7931C>T p.P2644L | Missense Mutation (SNP) | VAF 138/674 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.908); catalogued as rs1431862283; called by muse, mutect2, varscan2
- NOS1 | c.2020C>T p.R674W | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760044680, COSV100501455; called by muse, mutect2, varscan2
- NR3C2 | c.1411G>T p.G471* | Nonsense Mutation (SNP) | VAF 23/73 reads (32%) | catalogued as rs1553942839, COSV100679200; called by muse, mutect2, varscan2
- PIP4K2A | c.128G>T p.W43L | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.228); catalogued as rs184663145, COSV64865847; called by muse, mutect2, varscan2
- PPP1R3F | c.1661C>T p.T554M | Missense Mutation (SNP) | VAF 40/55 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs968825820, COSV99278774; called by muse, mutect2, varscan2
- PRAM1 | c.1822C>T p.L608F | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1169389305; called by muse, mutect2
- PRSS58 | c.117G>T p.L39F | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.939); catalogued as rs367758482; called by muse, mutect2, varscan2
- RAD54L | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 93/178 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64337092; called by muse, mutect2, varscan2
- SLC10A6 | c.326dup p.T110Hfs*4 | Frame Shift Ins (INS) | VAF 49/117 reads (42%) | catalogued as rs753933531; called by mutect2*, pindel, varscan2*
- SLC14A2 | c.2354G>T p.G785V | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54909141; called by muse, mutect2, varscan2
- SUSD5 | c.461G>C p.R154P | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV58880204; called by muse, mutect2, varscan2
- TRMT10B | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT tolerated (0.05); PolyPhen benign (0.022); catalogued as rs531666438; called by muse, mutect2, varscan2
- TTC22 | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs145786276; called by muse, mutect2, varscan2
- YME1L1 | c.128A>G p.H43R | Missense Mutation (SNP) | VAF 130/201 reads (65%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.05); catalogued as rs1253684258; called by muse, mutect2, varscan2
- ZNF638 | c.4748A>T p.K1583M | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV52481815; called by muse, mutect2, varscan2
- ZNF780A | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 82/214 reads (38%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.985); catalogued as rs751047796, COSV61815736; called by muse, mutect2, varscan2
- ALOX15B | c.1565A>T p.N522I | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- CCDC190 | c.386G>A p.G129D | Missense Mutation (SNP) | VAF 187/505 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- CCR3 | c.16G>C p.D6H | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- COL22A1 | c.1361C>A p.P454Q | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL27A1 | c.5099T>G p.M1700R | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- CORO6 | c.633+1G>C p.X211_splice | Splice Site (SNP) | VAF 15/41 reads (37%) | called by muse, mutect2, varscan2
- CTHRC1 | c.241C>G p.P81A | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- DISC1 | c.1914G>C p.K638N | Missense Mutation (SNP) | VAF 37/183 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- ESF1 | c.2540dup p.Q848Afs*14 | Frame Shift Ins (INS) | VAF 21/41 reads (51%) | called by mutect2, pindel, varscan2
- EYS | c.597C>G p.S199R | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- FNDC3A | c.3043G>A p.E1015K (on ENST00000492622 / NM_001079673.2; = p.E959K on NM_014923.5) | Missense Mutation (SNP) | VAF 31/40 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- GDF6 | c.315C>G p.Y105* | Nonsense Mutation (SNP) | VAF 57/264 reads (22%) | called by muse, mutect2, varscan2
- GLRA3 | c.295C>G p.Q99E | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- HDAC6 | c.1261C>A p.Q421K | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KCNH7 | c.1244T>A p.L415Q | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- KIR3DL3 | c.219C>A p.N73K | Missense Mutation (SNP) | VAF 117/237 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- LRFN5 | c.1843G>T p.E615* | Nonsense Mutation (SNP) | VAF 16/53 reads (30%) | called by muse, mutect2, varscan2
- LTBP4 | c.669C>G p.H223Q (on ENST00000308370 / NM_001042544.1; = p.H186Q on NM_003573.2) | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- LTN1 | c.5272_5279del p.C1758Vfs*3 | Frame Shift Del (DEL) | VAF 24/79 reads (30%) | called by mutect2, pindel, varscan2
- LYST | c.4487_4488insAAAA p.I1497Kfs*14 | Frame Shift Ins (INS) | VAF 83/118 reads (70%) | called by mutect2, varscan2
- MAP3K4 | c.2548dup p.Y850Lfs*22 | Frame Shift Ins (INS) | VAF 17/50 reads (34%) | called by mutect2, pindel, varscan2
- MDN1 | c.5905C>G p.P1969A | Missense Mutation (SNP) | VAF 35/294 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- MYOF | c.859G>T p.V287F | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- NRXN1 | c.1912T>G p.Y638D | Missense Mutation (SNP) | VAF 83/242 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- NSL1 | c.120C>A p.C40* | Nonsense Mutation (SNP) | VAF 21/179 reads (12%) | called by muse, mutect2, varscan2
- PARD3 | c.3712G>C p.D1238H | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDZD8 | c.3082C>T p.P1028S | Missense Mutation (SNP) | VAF 6/137 reads (4%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.997); called by muse, mutect2
- PEX14 | c.775C>A p.H259N | Missense Mutation (SNP) | VAF 54/100 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIGC | c.155T>A p.V52E | Missense Mutation (SNP) | VAF 55/343 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PIK3R1 | c.1342_1386del p.K448_E462del (on ENST00000521381 / NM_181523.3; = p.K178_E192del on NM_181504.4) | In Frame Del (DEL) | VAF 20/48 reads (42%) | called by mutect2, pindel
- PKD1L1 | c.4253A>C p.E1418A | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PLEKHA4 | c.889_895del p.P297Efs*70 | Frame Shift Del (DEL) | VAF 30/128 reads (23%) | called by mutect2, pindel
- PLXNA1 | c.2534C>A p.A845D | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.11); called by muse, mutect2
- PROCR | c.376A>G p.R126G | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- RCN2 | c.149A>C p.D50A | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious (0.02); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- RIF1 | c.7360T>G p.S2454A | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- RLF | c.3583C>T p.H1195Y | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RTL5 | c.1100G>T p.R367M | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- SCUBE2 | c.1352C>A p.T451K | Missense Mutation (SNP) | VAF 36/42 reads (86%) | SIFT tolerated (0.83); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- SGO1 | c.656A>T p.K219M | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.109); called by muse, mutect2
- SLC10A6 | c.328dup p.T110Nfs*4 | Frame Shift Ins (INS) | VAF 62/84 reads (74%) | called by mutect2, varscan2
- SLC37A3 | c.1180_1182del p.F394del | In Frame Del (DEL) | VAF 6/59 reads (10%) | called by mutect2, pindel
- SLC5A7 | c.1481T>G p.I494S | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SPIDR | c.1936C>G p.R646G | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); called by muse, mutect2
- SPTA1 | c.7136C>A p.A2379D | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- SRPX2 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT tolerated (0.85); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SVEP1 | c.622G>T p.A208S | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- SYBU | c.922C>A p.R308S (on ENST00000276646 / NM_001099754.2; = p.R307S on NM_017786.6) | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TEX13B | c.200G>T p.C67F | Missense Mutation (SNP) | VAF 174/193 reads (90%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- VPS13B | c.11907del p.S3970Afs*43 | Frame Shift Del (DEL) | VAF 27/149 reads (18%) | called by mutect2, pindel, varscan2
- WNK2 | c.2409_2419del p.I804Gfs*116 | Frame Shift Del (DEL) | VAF 27/54 reads (50%) | called by mutect2, pindel, varscan2
- ZNF749 | c.2182G>T p.E728* | Nonsense Mutation (SNP) | VAF 24/89 reads (27%) | called by muse, mutect2, varscan2
- AIFM2 | c.927C>T p.I309= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as rs201852745, COSV57159710, COSV57160782; called by muse, mutect2, varscan2
- ARRB1 | c.801G>T p.T267= | Silent (SNP) | VAF 37/296 reads (13%) | catalogued as COSV63576589; called by muse, mutect2, varscan2
- ASTN2 | c.2157G>A p.T719= (on ENST00000313400 / NM_001365069.1; = p.T668= on NM_014010.5) | Silent (SNP) | VAF 125/139 reads (90%) | catalogued as rs369400081; called by muse, mutect2, varscan2
- CD55 | c.541T>C p.L181= | Silent (SNP) | VAF 21/84 reads (25%) | called by muse, mutect2, varscan2
- CHST2 | c.901C>T p.L301= | Silent (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2
- CYREN | c.354G>T p.L118= | Silent (SNP) | VAF 31/117 reads (26%) | called by muse, mutect2, varscan2
- DMPK | c.1551C>T p.V517= | Silent (SNP) | VAF 20/75 reads (27%) | called by muse, mutect2, varscan2
- DNAJC13 | c.3066C>G p.S1022= | Silent (SNP) | VAF 11/97 reads (11%) | called by muse, mutect2, varscan2
- EXPH5 | c.921A>G p.K307= | Silent (SNP) | VAF 12/37 reads (32%) | called by muse, mutect2, varscan2
- LOXL2 | c.1767C>T p.P589= | Silent (SNP) | VAF 9/62 reads (15%) | called by muse, mutect2, varscan2
- MAGEB6 | c.849G>A p.P283= | Silent (SNP) | VAF 32/322 reads (10%) | catalogued as rs1157318101, COSV66872083; called by muse, mutect2
- NAPEPLD | c.402G>A p.T134= | Silent (SNP) | VAF 52/117 reads (44%) | catalogued as rs1014978968, COSV58522484; called by muse, mutect2, varscan2
- NPAP1 | c.1680C>T p.N560= | Silent (SNP) | VAF 46/119 reads (39%) | catalogued as rs770893029, COSV61510835; called by muse, mutect2, varscan2
- NTN5 | c.237C>T p.S79= | Silent (SNP) | VAF 35/56 reads (63%) | called by muse, mutect2, varscan2
- OR10J5 | c.717C>T p.T239= | Silent (SNP) | VAF 6/144 reads (4%) | called by muse, mutect2
- PGAP1 | c.2541T>G p.L847= | Silent (SNP) | VAF 35/54 reads (65%) | called by muse, mutect2, varscan2
- PPRC1 | c.3006G>A p.L1002= | Silent (SNP) | VAF 9/88 reads (10%) | called by muse, mutect2
- SLC18A2 | c.369C>T p.D123= | Silent (SNP) | VAF 21/106 reads (20%) | called by muse, mutect2, varscan2
- SPACA9 | c.240C>T p.C80= | Silent (SNP) | VAF 31/268 reads (12%) | catalogued as rs1445749293; called by muse, mutect2, varscan2
- SVIL | c.138C>T p.S46= | Silent (SNP) | VAF 21/40 reads (53%) | catalogued as rs371700516; called by muse, mutect2, varscan2
- XAF1 | c.882A>G p.G294= | Silent (SNP) | VAF 5/26 reads (19%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503713 T>G | 5'Flank (SNP) | VAF 46/92 reads (50%) | called by muse, mutect2, varscan2
- OR2T1 | c.-18G>A | 5'UTR (SNP) | VAF 28/110 reads (25%) | catalogued as rs193920936, COSV63542614; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRPM3 | c.184-256784G>T | Intron (SNP) | VAF 87/93 reads (94%) | called by muse, mutect2, varscan2
